Somatic mutation profile of tumor specimen TCGA-HT-7681-01A (aliquot TCGA-HT-7681-01A-11D-2395-08) from TCGA case TCGA-HT-7681, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 29.5 years (10,790 days).
Specimen TCGA-HT-7681-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 22a25474-b754-4ea6-9ef6-843552483fa3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7681-10A (Blood Derived Normal), aliquot TCGA-HT-7681-10C-01D-2396-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ac51ed7e-7953-4b99-bb4d-0f9944013892

The open-access MAF lists 14 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 8, Silent 2, Nonsense Mutation 2, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CIC | c.643C>T p.R215W | Missense Mutation (SNP) | VAF 18/58 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1568504941, COSV50547203; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- IDH2 | c.515G>A p.R172K | Missense Mutation (SNP) | VAF 22/78 reads (28%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs121913503, COSV57468734, COSV57468971, COSV57472976; ClinVar: pathogenic / not provided / likely pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.16342C>T p.R5448* | Nonsense Mutation (SNP) | VAF 9/20 reads (45%) | catalogued as rs1422752351, CM114906, COSV56418474; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AFF2 | c.3267G>T p.L1089= | Splice Region (SNP) | VAF 21/69 reads (30%) | catalogued as rs782088318, COSV53997652; called by muse, mutect2, varscan2
- BCAN | c.2630C>A p.A877D | Missense Mutation (SNP) | VAF 2/9 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.193); catalogued as COSV61258007; called by muse, mutect2
- BRCA2 | c.3273A>C p.L1091F | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); catalogued as rs1566228204, COSV66457572; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPATCH2L | c.1355G>A p.W452* | Nonsense Mutation (SNP) | VAF 15/74 reads (20%) | catalogued as rs751557267, COSV55049744; called by muse, mutect2, varscan2
- IL2RB | c.1420C>T p.P474S | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.117); catalogued as COSV53427478; called by muse, mutect2, varscan2
- INF2 | c.1717C>T p.P573S | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.607); catalogued as rs1484813694, COSV53034218; called by muse, mutect2, varscan2
- MORF4L2 | c.100A>G p.M34V | Missense Mutation (SNP) | VAF 53/114 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as COSV64611165; called by muse, mutect2, varscan2
- OR11H6 | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as rs201233405; called by muse, mutect2, varscan2
- SAMD4A | c.1621dup p.R541Kfs*111 | Frame Shift Ins (INS) | VAF 26/114 reads (23%) | called by mutect2, varscan2
- SYAP1 | c.733C>A p.R245= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV101204984, COSV66468387; called by muse, mutect2, varscan2
- ZNF687 | c.150A>G p.E50= | Silent (SNP) | VAF 32/86 reads (37%) | catalogued as COSV60680768; called by muse, mutect2, varscan2
